Somatic mutation profile of tumor specimen TCGA-DO-A1K0-01A (aliquot TCGA-DO-A1K0-01A-11D-A13W-08) from TCGA case TCGA-DO-A1K0, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 30.7 years (11,216 days).
Specimen TCGA-DO-A1K0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36da714b-bc66-442c-a1e3-1dda83d43fd3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DO-A1K0-10A (Blood Derived Normal), aliquot TCGA-DO-A1K0-10A-01D-A13W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a0d877b-5a67-4cf5-a650-7b68421c7bc6

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Frame Shift Ins 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- FAM78A | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771097879, COSV55991838; called by muse, mutect2, varscan2
- OR2T33 | c.52C>A p.H18N | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.558); catalogued as COSV58817715; called by muse, mutect2, varscan2
- ZFHX3 | c.4712A>G p.H1571R | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1232621310, COSV51733763; called by muse, mutect2, varscan2
- GBF1 | c.2286dup p.D763* (on ENST00000369983 / NM_001377137.1; = p.D762* on NM_004193.3) | Frame Shift Ins (INS) | VAF 54/132 reads (41%) | called by mutect2, pindel, varscan2
- GRIA3 | c.2661T>C p.Y887= | Silent (SNP) | VAF 12/145 reads (8%) | catalogued as COSV52078586; called by muse, mutect2
